Somatic mutation profile of tumor specimen TCGA-CV-7255-01A (aliquot TCGA-CV-7255-01A-11D-2012-08) from TCGA case TCGA-CV-7255, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 32.7 years (11,931 days).
Specimen TCGA-CV-7255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7314580c-7134-4b13-9d40-0e84f205606a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7255-10A (Blood Derived Normal), aliquot TCGA-CV-7255-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ae9b430-a9b2-4616-a98e-2e78e331fbf0

The open-access MAF lists 111 somatic variants for this specimen: 85 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 64, Silent 26, Frame Shift Del 10, Splice Site 3, In Frame Del 3, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 89/109 reads (82%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.092); catalogued as rs1017802235, COSV99698955; called by muse, mutect2, varscan2
- AGPAT1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV100421663; called by muse, mutect2, varscan2
- AKAP10 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs139003893; called by muse, mutect2, varscan2
- ATAD2B | c.2824C>T p.R942C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs746457919, COSV53198420; called by mutect2, varscan2
- BRWD3 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100956158; called by muse, mutect2, varscan2
- C6 | c.1783del p.Q595Nfs*36 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | catalogued as rs767886734; called by mutect2, pindel, varscan2
- CCL25 | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV99495183; called by muse, mutect2
- CFL1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100354089; called by muse, mutect2, varscan2
- CHD8 | c.851C>T p.S284L (on ENST00000646647 / NM_001170629.2; = p.S5L on NM_020920.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs1448310797, COSV101303150; called by muse, mutect2, varscan2
- COL13A1 | c.979G>T p.G327C (on ENST00000398978 / NM_001130103.2; = p.G270C on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637514; called by muse, mutect2, varscan2
- CPTP | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs770647006, COSV100028092; called by muse, mutect2, varscan2
- CSMD2 | c.5863C>G p.R1955G | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936708, COSV99591196; called by muse, mutect2, varscan2
- CSMD3 | c.10609A>G p.M3537V (on ENST00000297405 / NM_001363185.1; = p.M3368V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99836452; called by muse, mutect2, varscan2
- DCAF12L1 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100948331; called by muse, mutect2, varscan2
- DNTTIP2 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV63283911; called by muse, mutect2, varscan2
- DPPA2 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101524771; called by muse, mutect2, varscan2
- DUSP28 | c.441G>T p.W147C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99802320; called by muse, mutect2, varscan2
- EBNA1BP2 | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 50/147 reads (34%) | catalogued as COSV99355988; called by muse, mutect2, varscan2
- EXD2 | c.676C>T p.R226C (on ENST00000312994 / NM_001193362.1; = p.R101C on NM_018199.3) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs762151815, COSV57278078, COSV57278257; called by muse, mutect2, varscan2
- FAM102A | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1015649358, COSV100305525; called by muse, mutect2, varscan2
- FCHO1 | c.1792T>A p.L598M | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV99406171; called by muse, mutect2, varscan2
- FKBP14 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99767153; called by muse, mutect2, varscan2
- FLG | c.9793G>A p.G3265R | Missense Mutation (SNP) | VAF 232/586 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs144217264; called by muse, mutect2, varscan2
- FREM2 | c.4412G>T p.C1471F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV99748629, COSV99749111; called by muse, mutect2, varscan2
- GREB1 | c.4360C>T p.R1454W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs763617152, COSV99303043; called by muse, mutect2, varscan2
- H2AC4 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99451514, COSV99451574; called by muse, mutect2, varscan2
- H4C9 | c.39A>C p.K13N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.378); catalogued as COSV100574905; called by muse, mutect2, varscan2
- HLA-B | c.659A>C p.D220A | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV101318098; called by muse, mutect2, varscan2
- HTT | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV100750856; called by muse, mutect2
- IL12B | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs139186048; called by muse, mutect2, varscan2
- IL9 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV99192431; called by muse, mutect2, varscan2
- ITGAV | c.1070A>T p.Q357L | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99655086; called by muse, mutect2, varscan2
- KRI1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100224825; called by muse, mutect2, varscan2
- LAMA4 | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99683748; called by muse, mutect2, varscan2
- LRP2 | c.8543G>A p.C2848Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788820; called by muse, mutect2, varscan2
- LYN | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV101571238; called by muse, mutect2, varscan2
- MACF1 | c.4518A>C p.Q1506H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99244912; called by muse, mutect2, varscan2
- MORF4L2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV64611458; called by muse, mutect2, varscan2
- MRPS28 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99398908; called by muse, mutect2, varscan2
- MS4A14 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100280496; called by muse, mutect2, varscan2
- MYO10 | c.3047C>G p.S1016* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV99945575; called by mutect2, varscan2
- MYO3B | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV100510499; called by muse, mutect2
- NPAP1 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs1381616838, COSV100275512; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs776154715; called by mutect2, varscan2
- OR8B12 | c.90T>A p.F30L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100172794; called by muse, mutect2, varscan2
- OTX2 | c.866del p.L289Cfs*5 (on ENST00000408990 / NM_172337.3; = p.L297Cfs*5 on NM_021728.4) | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV100257805; called by mutect2, pindel, varscan2
- OVGP1 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.306); catalogued as COSV100868177, COSV63858778; called by muse, mutect2, varscan2
- PAGR1 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56190243; called by muse, mutect2, varscan2
- PCSK5 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV100950266; called by muse, mutect2, varscan2
- PDZD7 | c.1435A>G p.R479G | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV100931644; called by muse, mutect2, varscan2
- PHKA2 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV101177137; called by muse, mutect2, varscan2
- PLXDC1 | c.372A>G p.I124M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs1159547025, COSV100195446; called by muse, mutect2, varscan2
- PTPRT | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs61753667, COSV61996547; called by muse, mutect2, varscan2
- RFX6 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100263822; called by muse, mutect2, varscan2
- SCNN1G | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.339); catalogued as COSV100264258; called by muse, mutect2, varscan2
- SERPINB10 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99449294; called by muse, mutect2, varscan2
- SERPINF1 | c.534A>T p.Q178H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99628860; called by muse, mutect2, varscan2
- SLC12A5 | c.2017C>T p.L673F (on ENST00000454036 / NM_001134771.2; = p.L650F on NM_020708.5) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99716202; called by muse, mutect2
- SLF2 | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.801); catalogued as COSV99489293; called by muse, mutect2, varscan2
- SOX9 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs778047936, COSV55421835, COSV55423870; called by muse, mutect2, varscan2
- SPTBN2 | c.6680G>A p.R2227H | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370257588; called by muse, mutect2, varscan2
- SYTL5 | c.1879A>G p.K627E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99937334; called by muse, mutect2, varscan2
- TFR2 | c.473+2T>C p.X158_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99355589; called by muse, mutect2, varscan2
- TMEM62 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99543685; called by muse, mutect2
- TNN | c.3784G>A p.G1262R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53436224; called by muse, mutect2, varscan2
- TSACC | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV100966211; called by muse, mutect2, varscan2
- TTN | c.28699G>C p.E9567Q (on ENST00000591111; = p.E8640Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | PolyPhen benign (0.012); catalogued as COSV100616654; called by muse, mutect2, varscan2
- TTN | c.17065C>A p.L5689M (on ENST00000591111; = p.L4762M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/123 reads (28%) | PolyPhen probably damaging (0.999); catalogued as COSV100616656; called by muse, mutect2, varscan2
- UNC5A | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56173570, COSV99994658; called by muse, mutect2, varscan2
- VTN | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs150566083; called by muse, mutect2, varscan2
- XIRP2 | c.6131del p.T2044Nfs*4 (on ENST00000628543; = p.T2219Nfs*4 on NM_152381.6) | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | catalogued as COSV99736706; called by mutect2, pindel, varscan2
- ZCCHC17 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100704032; called by muse, mutect2, varscan2
- CDKN2A | c.465del p.D156Ifs*37 | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- CLEC4F | c.311_322del p.I104_F107del | In Frame Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel
- DNHD1 | c.11746del p.R3916Afs*8 | Frame Shift Del (DEL) | VAF 21/145 reads (14%) | called by mutect2, pindel, varscan2
- KDM3B | c.1774_1777del p.K592Cfs*18 | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- LUZP2 | c.460-10_461del p.X154_splice | Splice Site (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- MMP15 | c.1514dup p.S505Rfs*11 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- NAV1 | c.4683_4691del p.G1563_T1565del | In Frame Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- OR4M1 | c.565del p.C189Vfs*9 | Frame Shift Del (DEL) | VAF 34/281 reads (12%) | called by mutect2, varscan2
- PXMP4 | c.103_107del p.N35Gfs*85 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- SLC2A1 | c.656_659dup p.E221Rfs*17 | Frame Shift Ins (INS) | VAF 19/136 reads (14%) | called by mutect2, pindel, varscan2
- STIL | c.2836_2851del p.N946Vfs*14 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- VPS13B | c.10979_10987del p.P3660_S3662del | In Frame Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel
- ANKLE2 | c.582G>A p.K194= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100514189; called by muse, mutect2, varscan2
- COQ6 | c.834A>C p.A278= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV99473971; called by muse, mutect2, varscan2
- CSMD3 | c.7050C>T p.I2350= (on ENST00000297405 / NM_001363185.1; = p.I2246= on NM_052900.3) | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as rs142588028, COSV99846430; called by muse, mutect2, varscan2
- CTCFL | c.558G>A p.Q186= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV99712841; called by muse, mutect2, varscan2
- DPEP1 | c.270G>A p.Q90= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99878549; called by muse, varscan2
- GPER1 | c.771G>A p.A257= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs758236330, COSV99867137; called by muse, mutect2, varscan2
- GRIA1 | c.315C>T p.H105= | Silent (SNP) | VAF 52/112 reads (46%) | catalogued as rs138090704; called by muse, mutect2, varscan2
- GRIA4 | c.714C>A p.I238= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99232018; called by muse, mutect2, varscan2
- ITCH | c.1212T>C p.R404= (on ENST00000262650 / NM_001257137.3; = p.R363= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV99392618; called by muse, mutect2, varscan2
- MAGT1 | c.513C>T p.A171= (on ENST00000618282 / NM_001367916.1; = p.A203= on NM_032121.5) | Silent (SNP) | VAF 71/239 reads (30%) | catalogued as rs186479035, COSV63781246; called by muse, mutect2, varscan2
- MC2R | c.51T>C p.N17= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100563030; called by muse, mutect2, varscan2
- MUC5B | c.6867C>T p.S2289= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as COSV101500414; called by muse, mutect2, varscan2
- OR6C4 | c.864T>C p.Y288= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1157038510, COSV67792764; called by muse, mutect2, varscan2
- PLSCR4 | c.480A>T p.T160= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100724234; called by muse, mutect2
- RAMP2 | c.474C>T p.P158= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99519761; called by muse, mutect2, varscan2
- SLC26A7 | c.975T>C p.A325= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs768349832, COSV52598401; called by muse, mutect2, varscan2
- SLCO6A1 | c.117G>A p.P39= | Silent (SNP) | VAF 111/172 reads (65%) | catalogued as rs1232941592, COSV65808252; called by muse, mutect2, varscan2
- TNPO3 | c.957G>A p.G319= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99603038; called by muse, mutect2, varscan2
- TRIM45 | c.465C>T p.C155= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs1357342753, COSV99868525; called by muse, mutect2, varscan2
- TRO | c.2151C>A p.A717= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99436592; called by muse, mutect2, varscan2
- TSC22D1 | c.1041T>C p.A347= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV101488118; called by muse, mutect2, varscan2
- TXNDC2 | c.246C>T p.A82= (on ENST00000306084 / NM_001098529.2; = p.A15= on NM_032243.6) | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs200597390; called by muse, mutect2, varscan2
- VN1R1 | c.249G>A p.T83= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs143275734; called by muse, mutect2, varscan2
- ZNF827 | c.147G>A p.Q49= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV101061427; called by muse, mutect2, varscan2
- ZXDA | c.159C>T p.G53= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100699434; called by muse, mutect2, varscan2
- ZXDB | c.891C>T p.S297= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100885944; called by muse, mutect2
